Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6347, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6347-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE

SPECIMEN(S):

A. PROSTATE

GROSS DESCRIPTION:

A. PROSTATE

Received fresh is a 59g resected prostate 4.0cm from apex to base, 4.5cm from anterior to posterior and 5.5cm from right to left with attached right and left seminal vesicle and vas deferens. The capsule is tan pink smooth and intact. The specimen is inked as follows: Apex-Red, Anterior-Orange, Right Lateral-Green, Left Lateral-Yellow, Base-Blue, Posterior-Black. After removal of the apex and base, the remaining prostate weight is 32g. The specimen is serially sectioned from apex to base to reveal beige tan spongy tissue. The attached right and left seminal vesicles are 5.0 x 1.5 x 1.0cm and 3.5 x 2.0 x 1.0cm respectively, are sectioned to reveal beige tan cystic structure with no gross evidence of tumor involvement. The attached right and left vas deferens are 3.0 x 0.6cm and 3.5 x 0.5cm respectively, are sectioned to reveal beige tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Levels II and IV). The remainder of the specimen is submitted as follows:

A1-A2: right apex
A3-A4: left apex
A5: Level I right anterior
A6: Level I right posterior
A7: Level I left anterior
A8-A9: Level I left posterior
A10: Level II right anterior capsule
A11: Level II right posterior capsule
A12: Level II left anterior capsule
A13: Level II left posterior capsule
A14: Level III right anterior
A15: Level III right posterior
A16: Level III left anterior
A17: Level III left posterior
A18: Level IV right anterior capsule
A19: Level IV right posterior capsule
A20: Level IV left anterior capsule
A21: Level IV left posterior capsule
A22-A23: right base with periurethral margin
A24-A25: left base with periurethral margin
A26: right lateral base
A27: left lateral base
A28: right base
A29: left base
A30: right seminal vesicle and vas deferens
A31: left seminal vesicle and vas deferens

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON SCORE 6 (3 + 3), PRESENT IN BILATERAL PROSTATE FROM APEX TO MID
- CARCINOMA INVOLVING APPROXIMATELY 25% OF PROSTATIC GLAND
- SURGICAL RESECTION MARGINS, NEGATIVE FOR TUMOR
- NO EXTRAPROSTATIC EXTENSION IDENTIFIED
- BILATERAL SEMINAL VESICLE, NEGATIVE FOR TUMOR
- SEE TEMPLATE

SYNOPTIC REPORT - PROSTATE GLAND

Location: Bilateral from apex to mid, peripheral zones

WHO CLASSIFICATION

Epithelial tumors

[page 2 of 2]
Adenocarcinoma 8140/3
Multicentricity: Yes
Gland Involvement: 25%
Gleason Grade/Sum:: Grade 3 + 3 , Sum 6
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: No
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Post Hormonal Therapy Change: No
Lymph Nodes: No lymph nodes sampled
Other Pathologic Findings: BPH
Pathological Staging (pTNM): p T2c N x M x

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Prostate Cancer

Source: NCI Genomic Data Commons file 024c93f3-ad3f-4bb9-93ff-b27bbd526f65 (TCGA-G9-6347.2ED4FCE8-5DCF-4529-95E5-C454529D7971.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).